Somatic mutation profile of tumor specimen TCGA-60-2723-01A (aliquot TCGA-60-2723-01A-01D-1522-08) from TCGA case TCGA-60-2723, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,225 days).
Specimen TCGA-60-2723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 171f8a05-bc95-4c5f-8a0c-e5c319462ffe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2723-11A (Solid Tissue Normal), aliquot TCGA-60-2723-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4e9b219-f8d7-4000-8523-41388561d97b

The open-access MAF lists 294 somatic variants for this specimen: 240 protein-altering or splice-affecting, 51 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 51, Frame Shift Del 12, Nonsense Mutation 9, Splice Region 4, Intron 3, Splice Site 3, Frame Shift Ins 3, In Frame Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4229C>A p.S1410Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as COSV70043399; called by muse, mutect2, varscan2
- ABCD2 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 71/369 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV58055017; called by muse, mutect2, varscan2
- AC004593.2 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 81/164 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as rs934664832, COSV56095903; called by muse, mutect2, varscan2
- ACSM1 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54639929; called by muse, mutect2, varscan2
- ACTL6B | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50518325; called by muse, mutect2, varscan2
- ADAMTS12 | c.4451C>A p.S1484Y | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV61278656; called by muse, mutect2, varscan2
- ADAMTS20 | c.2365G>A p.V789M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV67138751; called by muse, mutect2
- ADCY8 | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 128/483 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475267602, COSV53905124; called by muse, mutect2, varscan2
- ADCY8 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53926260; called by muse, mutect2, varscan2
- ADGRG7 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56299253; called by muse, mutect2, varscan2
- AFF1 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561558992, COSV57117810; called by muse, mutect2, varscan2
- AGAP2 | c.1683G>C p.E561D (on ENST00000547588 / NM_001122772.2; = p.E225D on NM_014770.4) | Missense Mutation (SNP) | VAF 205/553 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.018); catalogued as COSV57728167, COSV57730210, COSV57731479; called by muse, mutect2, varscan2
- ALPG | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99779406; called by muse, mutect2, varscan2
- ANAPC1 | c.4537G>T p.E1513* | Nonsense Mutation (SNP) | VAF 48/154 reads (31%) | catalogued as COSV61979368; called by muse, varscan2
- AOC1 | c.1742G>T p.S581I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62870731; called by muse, mutect2, varscan2
- APOBEC1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57550175, COSV99981018; called by muse, mutect2, varscan2
- APOBEC3D | c.793A>G p.R265G | Missense Mutation (SNP) | VAF 202/596 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1400558719, COSV53328645; called by muse, varscan2
- ARHGEF4 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58123575, COSV58129852; called by muse, mutect2, varscan2
- ATP7A | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 206/534 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV58453549; called by muse, mutect2, varscan2
- BCHE | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV52262192; called by muse, mutect2, varscan2
- BIRC6 | c.4047G>C p.Q1349H | Missense Mutation (SNP) | VAF 85/168 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV70205518; called by muse, mutect2, varscan2
- CACNA1E | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62392498, COSV62416591; called by muse, mutect2, varscan2
- CACNA1S | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs545411173, COSV62943438; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CACNA2D4 | c.1619T>A p.L540Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54959609; called by muse, mutect2, varscan2
- CACNB3 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV56400839; called by muse, mutect2, varscan2
- CADPS2 | c.2756G>T p.C919F | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV57384765; called by muse, mutect2, varscan2
- CALHM4 | c.750G>T p.K250N (on ENST00000368596 / NM_001366078.1; = p.K64N on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as COSV63985748, COSV63985933; called by muse, mutect2, varscan2
- CCDC27 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV53901618; called by muse, mutect2, varscan2
- CCM2L | c.1170C>G p.S390R (on ENST00000452892 / NM_001365692.1; = p.A369G on NM_080625.4) | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV52952552; called by muse, mutect2, varscan2
- CCN4 | c.444C>A p.D148E | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.28); catalogued as COSV51532431, COSV51535531; called by muse, mutect2, varscan2
- CD209 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 108/330 reads (33%) | catalogued as COSV52658533; called by muse, varscan2
- CD300LF | c.671T>A p.L224H | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.339); catalogued as COSV56899056; called by muse, mutect2, varscan2
- CD96 | c.715T>C p.F239L (on ENST00000283285 / NM_198196.3; = p.F223L on NM_005816.5) | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV51922661; called by muse, mutect2, varscan2
- CDH18 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776963132, COSV56899350; called by muse, mutect2
- CDH2 | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52295468, COSV52295962; called by muse, mutect2, varscan2
- CDK15 | c.886G>T p.G296C (on ENST00000652192 / NM_001366386.2; = p.G245C on NM_139158.2) | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53638345, COSV99643813; called by muse, mutect2
- CECR2 | c.2200A>G p.I734V (on ENST00000342247 / NM_001290047.2; = p.I551V on NM_001290046.1) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV52847780; called by muse, mutect2, varscan2
- CEP72 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV53796905; called by muse, mutect2, varscan2
- CLTCL1 | c.3063C>T p.H1021= | Splice Region (SNP) | VAF 18/94 reads (19%) | catalogued as rs1041665106, COSV54238700; called by muse, mutect2, varscan2
- CLVS2 | c.537G>C p.M179I | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51568777; called by muse, mutect2, varscan2
- CNTNAP2 | c.2375A>G p.Q792R | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1445975540, COSV62252473; called by muse, mutect2, varscan2
- CNTNAP4 | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as COSV56699258; called by muse, mutect2, varscan2
- CNTROB | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV58049894; called by muse, mutect2, varscan2
- COL11A1 | c.1245C>A p.S415R | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.339); catalogued as rs371490794, COSV62185051, COSV62196610; called by muse, mutect2, varscan2
- COL12A1 | c.8098G>T p.A2700S | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV59392888, COSV59407435; called by muse, mutect2, varscan2
- COL1A2 | c.1945G>A p.G649S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51957004, COSV51965780; called by muse, mutect2, varscan2
- COL22A1 | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57331225, COSV57359419; called by muse, mutect2, varscan2
- CSMD2 | c.8847C>A p.V2949= | Splice Region (SNP) | VAF 32/105 reads (30%) | catalogued as COSV53959619; called by muse, mutect2, varscan2
- CYBB | c.865del p.W289Gfs*24 | Frame Shift Del (DEL) | VAF 58/493 reads (12%) | catalogued as COSV66085572; called by mutect2, pindel, varscan2
- CYLC2 | c.843C>G p.D281E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs201302612, COSV66336518, COSV66339368; called by muse, mutect2, varscan2
- DCC | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.899); catalogued as COSV71440297; called by muse, mutect2, varscan2
- DCDC2 | c.1284C>A p.D428E | Missense Mutation (SNP) | VAF 79/473 reads (17%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV65829820; called by muse, mutect2, varscan2
- DEPDC1B | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV99409761; called by muse, varscan2
- DEPDC1B | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99409763; called by muse, varscan2
- DGKK | c.2447G>T p.R816L | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV65708298, COSV65709338; called by muse, mutect2, varscan2
- DIO3 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63774572; called by muse, mutect2, varscan2
- DLG2 | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54683185, COSV54685776; called by muse, mutect2, varscan2
- DNAH10 | c.6478A>T p.M2160L (on ENST00000409039; = p.M2099L on NM_207437.3) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV69001075; called by muse, mutect2, varscan2
- DNAH3 | c.3498G>T p.K1166N | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV54549809, COSV54550066; called by muse, mutect2, varscan2
- DNAH8 | c.3496G>T p.D1166Y | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as COSV59478767; called by muse, mutect2, varscan2
- DNAH9 | c.12006C>G p.I4002M | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV52375639; called by muse, mutect2, varscan2
- DNAJC13 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV53457826; called by muse, mutect2
- DNAJC21 | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100331519; called by muse, mutect2, varscan2
- DZIP3 | c.2886G>T p.M962I | Missense Mutation (SNP) | VAF 256/644 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1330184909, COSV64313776; called by muse, mutect2, varscan2
- EML2 | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV55603722; called by muse, mutect2, varscan2
- ERBB2 | c.900C>T p.P300= | Splice Region (SNP) | VAF 31/67 reads (46%) | catalogued as COSV54082449; called by muse, mutect2, varscan2
- ERICH3 | c.3559G>T p.D1187Y | Missense Mutation (SNP) | VAF 126/425 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV58617774; called by muse, mutect2, varscan2
- F8 | c.3098A>T p.H1033L | Missense Mutation (SNP) | VAF 85/255 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV64278386; called by muse, mutect2, varscan2
- FABP5 | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs757111208, COSV51917918; called by muse, mutect2, varscan2
- FAM135B | c.2458G>A p.G820R | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV52752187; called by muse, mutect2, varscan2
- FAM135B | c.719G>T p.W240L | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV52749876; called by muse, mutect2, varscan2
- FCRL2 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as COSV63835042; called by muse, mutect2, varscan2
- FCRL3 | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV63844802; called by muse, mutect2, varscan2
- FGD5 | c.1474T>G p.Y492D | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.404); catalogued as COSV53251658; called by muse, mutect2, varscan2
- FGF2 | c.645C>A p.Y215* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as COSV52651315, COSV52652869; called by muse, mutect2, varscan2
- FOXD1 | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs746178308, COSV61076826; called by muse, mutect2, varscan2
- FRZB | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54556005; called by muse, mutect2, varscan2
- FYB1 | c.1394T>A p.I465K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60955999; called by muse, mutect2, varscan2
- GALNT5 | c.383A>T p.H128L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV52041092; called by muse, mutect2, varscan2
- GIMAP2 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV56236295; called by muse, mutect2, varscan2
- GK | c.1072G>A p.V358I (on ENST00000427190 / NM_001205019.2; = p.V352I on NM_000167.6) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as COSV66732565; called by muse, mutect2, varscan2
- GOLGA1 | c.1477A>G p.R493G | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs774962630, COSV63024251; called by muse, mutect2, varscan2
- GRM5 | c.1321del p.L441* | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | catalogued as COSV100549843; called by mutect2, pindel, varscan2
- H2AC17 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as rs372303389, COSV58153994; called by muse, mutect2, varscan2
- HAND2 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64019064; called by muse, mutect2, varscan2
- HCK | c.1445G>T p.C482F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52946984; called by muse, mutect2, varscan2
- HEG1 | c.3865G>T p.D1289Y | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769086150, COSV60765413; called by muse, mutect2, varscan2
- HGF | c.616T>C p.C206R | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55956463; called by muse, mutect2, varscan2
- HK3 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV52844295; called by muse, mutect2, varscan2
- HOMEZ | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV62537791; called by muse, mutect2, varscan2
- IGKV1-8 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 119/333 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1253171805; called by muse, mutect2, varscan2
- IL17F | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60235218; called by muse, mutect2, varscan2
- IL18RAP | c.1445G>A p.S482N | Missense Mutation (SNP) | VAF 67/285 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51829181; called by muse, mutect2, varscan2
- IL2RB | c.136T>G p.C46G | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53428461; called by muse, mutect2, varscan2
- IZUMO1R | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 75/363 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.801); catalogued as COSV60623506; called by muse, mutect2, varscan2
- JAG1 | c.3048T>A p.I1016= | Splice Region (SNP) | VAF 62/210 reads (30%) | catalogued as COSV54762518; called by muse, mutect2, varscan2
- JAK2 | c.2968G>C p.V990L | Missense Mutation (SNP) | VAF 745/925 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67671801; called by muse, mutect2, varscan2
- KCNK17 | c.503dup p.T169Hfs*6 | Frame Shift Ins (INS) | VAF 37/131 reads (28%) | catalogued as rs1289056210; called by mutect2, pindel, varscan2
- KEAP1 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as COSV50501375, COSV50643386; called by muse, mutect2, varscan2
- KIR3DL1 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 82/210 reads (39%) | catalogued as COSV58495866; called by muse, mutect2, varscan2
- KIRREL2 | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV52879953; called by muse, mutect2, varscan2
- LARP7 | c.1668+1G>T p.X556_splice | Splice Site (SNP) | VAF 36/82 reads (44%) | catalogued as COSV60522241; called by muse, mutect2, varscan2
- LDHAL6A | c.680G>C p.W227S | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52652779; called by muse, mutect2, varscan2
- LRFN5 | c.1551C>A p.C517* | Nonsense Mutation (SNP) | VAF 81/432 reads (19%) | catalogued as COSV53250921, COSV53274100; called by muse, mutect2, varscan2
- LRFN5 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs765807336, COSV53274108; called by muse, mutect2, varscan2
- LRRC37A2 | c.3689C>A p.A1230D | Missense Mutation (SNP) | VAF 63/366 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV61004380; called by muse, mutect2, varscan2
- MAGI2 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 127/399 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62697070; called by muse, mutect2, varscan2
- MARCO | c.205A>C p.N69H | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV59058416; called by muse, mutect2, varscan2
- MCM5 | c.385A>C p.K129Q | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV53348153; called by muse, mutect2, varscan2
- MED1 | c.4342C>G p.P1448A | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100327879, COSV56128385; called by muse, varscan2
- METTL6 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV67542605; called by muse, mutect2, varscan2
- MROH2B | c.2287G>T p.G763C | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV68189258; called by muse, mutect2, varscan2
- MST1R | c.500A>C p.H167P | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56573675; called by muse, mutect2, varscan2
- MUC17 | c.398C>G p.T133S | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV60302591; called by muse, mutect2, varscan2
- MUC17 | c.7809A>G p.I2603M | Missense Mutation (SNP) | VAF 89/562 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV60302599; called by muse, mutect2, varscan2
- MUC3A | c.7327C>A p.L2443I | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT deleterious, low confidence (0.02); catalogued as rs73163756; called by muse, mutect2, varscan2
- MUC3A | c.7328T>A p.L2443H | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious, low confidence (0); catalogued as rs750472138, COSV60224328; called by muse, mutect2, varscan2
- MYH1 | c.4269G>C p.Q1423H | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.285); catalogued as COSV56856779; called by muse, mutect2, varscan2
- MYH13 | c.5107C>A p.R1703S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52842071, COSV52842304; called by muse, mutect2, varscan2
- MYH13 | c.3502A>G p.N1168D | Missense Mutation (SNP) | VAF 103/277 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs759892824, COSV52842088; called by muse, mutect2, varscan2
- MYH4 | c.4661C>T p.S1554F | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV55125773; called by muse, mutect2, varscan2
- MYLK2 | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); catalogued as COSV65659915; called by muse, mutect2, varscan2
- MYPN | c.2189C>A p.T730K | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62738993; called by muse, mutect2, varscan2
- NAALAD2 | c.1447C>A p.L483M | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV58965905; called by muse, mutect2, varscan2
- NAV3 | c.5318C>G p.P1773R | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as rs1367201584, COSV57110792, COSV99894160; called by muse, mutect2, varscan2
- NCAPG2 | c.2231A>T p.K744I | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV51991553; called by muse, mutect2, varscan2
- NEMF | c.2388G>T p.L796F | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV53595146; called by muse, mutect2, varscan2
- NODAL | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54662575; called by muse, mutect2, varscan2
- NPHP4 | c.4168G>T p.G1390C | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65397685; called by muse, mutect2, varscan2
- NRAP | c.4886C>T p.P1629L (on ENST00000359988 / NM_001322945.2; = p.P1594L on NM_006175.4) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV63493784; called by muse, mutect2, varscan2
- NRCAM | c.3764T>C p.L1255P (on ENST00000379028 / NM_001371124.1; = p.L1134P on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/424 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61048431; called by muse, mutect2, varscan2
- NRP2 | c.1917G>T p.Q639H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55935239; called by muse, mutect2, varscan2
- OBSCN | c.8912G>C p.R2971P | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV52825882; called by muse, mutect2, varscan2
- OR10G9 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV66686805; called by muse, mutect2
- OR2A1 | c.499T>A p.F167I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101283407; called by mutect2, varscan2
- OR2AK2 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV63560536; called by muse, mutect2, varscan2
- OR2B3 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV65851176; called by muse, mutect2, varscan2
- OR2M2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 221/740 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV62899371; called by muse, varscan2
- OR4C6 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.102); catalogued as rs756494196, COSV58606184; called by muse, mutect2, varscan2
- OR4S2 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 162/514 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56748333; called by muse, varscan2
- OR4S2 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV56748343; called by muse, mutect2, varscan2
- OR51B4 | c.789A>T p.K263N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.33); catalogued as COSV66517750; called by muse, mutect2, varscan2
- OR5L2 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 152/331 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65725081; called by muse, mutect2, varscan2
- OR8J3 | c.755A>T p.Y252F | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56884159; called by muse, mutect2, varscan2
- OR9I1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV56927470; called by muse, mutect2
- PACS2 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.859); catalogued as rs782650153, COSV57657146; called by muse, mutect2, varscan2
- PAN3 | c.1721G>C p.G574A | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.971); catalogued as COSV56707334; called by muse, mutect2, varscan2
- PAPPA | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60277604, COSV60291325; called by muse, mutect2, varscan2
- PCDHB3 | c.2192C>A p.P731H | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV50605047; called by muse, mutect2, varscan2
- PCDHGA4 | c.2083G>T p.V695L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.316); catalogued as COSV54027165; called by muse, mutect2, varscan2
- PDP1 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as rs1429816363, COSV52603788; called by muse, mutect2, varscan2
- PIK3R2 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55850240; called by muse, mutect2, varscan2
- PKHD1L1 | c.3388C>G p.P1130A | Missense Mutation (SNP) | VAF 96/326 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV65752371; called by muse, mutect2, varscan2
- PKNOX2 | c.1262T>C p.M421T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV53554240; called by muse, mutect2, varscan2
- PLA2G6 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.442); catalogued as COSV59273390; called by muse, mutect2, varscan2
- PLPPR4 | c.2224A>T p.N742Y | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV64567633; called by muse, mutect2
- PRAME | c.1432A>T p.S478C | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV67162456; called by muse, mutect2, varscan2
- PREX1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64255951, COSV64256589; called by muse, mutect2, varscan2
- PRKCG | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV54732606; called by muse, mutect2, varscan2
- PRKCG | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV54732618; called by muse, mutect2, varscan2
- PRLR | c.683G>C p.S228T | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV51497109, COSV51500405; called by muse, mutect2, varscan2
- PROM1 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs371004406, COSV71699978; called by muse, mutect2, varscan2
- PRR23B | c.179T>C p.I60T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs756679983, COSV61494628; called by muse, mutect2, varscan2
- PUM2 | c.1104C>A p.N368K | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.127); catalogued as COSV57585190; called by muse, mutect2, varscan2
- RALGAPA2 | c.4656G>C p.M1552I | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.05); catalogued as COSV52510442; called by muse, mutect2, varscan2
- RALGPS2 | c.1748A>G p.E583G | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62685347; called by muse, mutect2, varscan2
- RCN2 | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV58031973; called by muse, mutect2, varscan2
- RFLNB | c.268C>G p.P90A | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.063); catalogued as COSV61239949; called by muse, mutect2, varscan2
- RFLNB | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV61239957; called by muse, mutect2, varscan2
- RNF148 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57360909; called by muse, mutect2, varscan2
- SAMD14 | c.838G>A p.D280N (on ENST00000330175 / NM_001257359.2; = p.D308N on NM_174920.4) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as COSV50304992; called by muse, mutect2, varscan2
- SAMD9 | c.4125A>T p.Q1375H | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66077415; called by muse, mutect2, varscan2
- SARDH | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs1198632722, COSV64097708; called by muse, mutect2, varscan2
- SCN2A | c.5878C>G p.P1960A | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV51854527; called by muse, mutect2, varscan2
- SDR16C5 | c.694del p.E232Kfs*23 | Frame Shift Del (DEL) | VAF 43/163 reads (26%) | catalogued as COSV100374090, COSV58125587; called by mutect2, pindel, varscan2
- SEL1L2 | c.678G>T p.L226F | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs1325897740, COSV53157974; called by muse, mutect2, varscan2
- SEMA6C | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59007613; called by muse, mutect2, varscan2
- SERPING1 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV53544250; called by muse, mutect2, varscan2
- SETD2 | c.6046T>C p.W2016R | Missense Mutation (SNP) | VAF 115/297 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57451226; called by muse, mutect2, varscan2
- SETX | c.7484T>C p.L2495P | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV56394210; called by muse, mutect2, varscan2
- SHC2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368659991; called by muse, mutect2, varscan2
- SLC6A12 | c.410T>A p.L137H | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62886133; called by muse, mutect2, varscan2
- SLC9B2 | c.996+1G>T p.X332_splice | Splice Site (SNP) | VAF 100/261 reads (38%) | catalogued as rs1242801717, COSV60022150; called by muse, mutect2, varscan2
- SNTG2 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs777135474, COSV58005400; called by muse, mutect2, varscan2
- SORCS1 | c.1781G>C p.G594A | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53903462; called by muse, mutect2, varscan2
- SPEG | c.9069G>C p.M3023I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV56679250; called by muse, mutect2, varscan2
- SPINT4 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV54142724, COSV54143294; called by muse, mutect2, varscan2
- SPRED1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 41/126 reads (33%) | catalogued as COSV104406857, COSV54438998; called by muse, mutect2, varscan2
- SULT1C2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547819243, COSV52267067; called by muse, mutect2, varscan2
- SYCP2 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV62772363; called by muse, mutect2, varscan2
- SYT6 | c.1440C>A p.N480K (on ENST00000610222 / NM_001366225.1; = p.N395K on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as COSV101059600, COSV65773774; called by muse, mutect2, varscan2
- TAF1L | c.3869G>T p.G1290V | Missense Mutation (SNP) | VAF 100/294 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54268755; called by muse, mutect2, varscan2
- TAF1L | c.3868G>T p.G1290* | Nonsense Mutation (SNP) | VAF 97/294 reads (33%) | catalogued as COSV54261123, COSV54268768; called by muse, mutect2, varscan2
- TECTA | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV50800057; called by muse, mutect2, varscan2
- TEP1 | c.7630C>T p.H2544Y | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs372031810; called by muse, mutect2, varscan2
- THY1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52455232; called by muse, mutect2, varscan2
- TLE6 | c.770C>T p.A257V (on ENST00000246112 / NM_001143986.2; = p.A134V on NM_024760.3) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1233031120, COSV55737715; called by muse, mutect2, varscan2
- TMEM108 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.06); catalogued as COSV58882517; called by muse, mutect2, varscan2
- TMEM248 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV58577824; called by muse, mutect2, varscan2
- TMPRSS7 | c.2097G>T p.Q699H (on ENST00000452346; = p.Q573H on NM_001042575.2) | Missense Mutation (SNP) | VAF 127/542 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69982511; called by muse, mutect2, varscan2
- TNNI3K | c.2281G>T p.A761S | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.985); catalogued as COSV53952223, COSV53953568; called by muse, mutect2, varscan2
- TONSL | c.3722G>T p.R1241L | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV52871180, COSV52873463; called by muse, mutect2, varscan2
- TOP1 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV63696011; called by muse, mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 198/444 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRPV5 | c.1807A>T p.M603L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV54689560; called by muse, mutect2, varscan2
- TTC7B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs771159231, COSV60637230; called by muse, mutect2, varscan2
- UBA1 | c.2639G>A p.R880Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as COSV60115380; called by muse, mutect2, varscan2
- UGT2B10 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55323357; called by muse, mutect2, varscan2
- ULK2 | c.2269G>T p.G757W | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs756637387, COSV64448357; called by muse, mutect2, varscan2
- USH1C | c.647T>A p.L216Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50034582; called by muse, mutect2
- USH2A | c.7452-1G>A p.X2484_splice | Splice Site (SNP) | VAF 47/155 reads (30%) | catalogued as COSV56431977; called by muse, mutect2, varscan2
- USP11 | c.1509G>T p.M503I (on ENST00000218348; = p.M460I on NM_001371072.1) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as COSV54475881; called by muse, mutect2, varscan2
- VCAM1 | c.2089C>G p.P697A | Missense Mutation (SNP) | VAF 118/412 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV54119671, COSV54121830; called by muse, mutect2, varscan2
- VDR | c.1196A>T p.K399M | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57470478; called by muse, mutect2, varscan2
- VSIG2 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52519461; called by muse, mutect2, varscan2
- WDR88 | c.745T>G p.S249A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63452669; called by muse, mutect2
- XIRP2 | c.3314A>T p.E1105V (on ENST00000628543; = p.E1280V on NM_152381.6) | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54732735; called by muse, mutect2, varscan2
- XPR1 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62555583, COSV62560399; called by muse, mutect2, varscan2
- ZC3HAV1L | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV51965103; called by muse, mutect2, varscan2
- ZNF202 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as rs150835875; called by muse, mutect2, varscan2
- ZNF398 | c.1606G>C p.E536Q (on ENST00000475153 / NM_170686.3; = p.E365Q on NM_020781.4) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60066760; called by muse, mutect2, varscan2
- ZNF561 | c.384G>T p.R128S | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57179015; called by muse, mutect2, varscan2
- ZNF561 | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV57179025; called by muse, mutect2, varscan2
- ZNF780A | c.1172G>A p.C391Y | Missense Mutation (SNP) | VAF 130/366 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61816683; called by muse, mutect2, varscan2
- ZNF99 | c.325A>T p.K109* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV68056677; called by muse, mutect2, varscan2
- A4GNT | c.84del p.C29Afs*18 | Frame Shift Del (DEL) | VAF 52/120 reads (43%) | called by mutect2, pindel, varscan2
- CIITA | c.2959_2967del p.Q987_L989del | In Frame Del (DEL) | VAF 30/108 reads (28%) | called by mutect2, pindel, varscan2
- COL1A2 | c.4007del p.P1336Hfs*33 | Frame Shift Del (DEL) | VAF 89/360 reads (25%) | called by mutect2, pindel, varscan2
- FMN2 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.231); called by muse, varscan2
- GFRA2 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IDE | c.1309delinsGT p.I437Vfs*24 | Frame Shift Ins (INS) | VAF 69/325 reads (21%) | called by pindel, varscan2*
- IGDCC3 | c.436del p.Q146Rfs*24 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | called by mutect2, pindel, varscan2
- IGHV3-15 | c.83del p.G28Efs*4 | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | called by mutect2, pindel, varscan2
- NYAP2 | c.945del p.K316Rfs*57 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- REG1A | c.320dup p.N108Efs*26 | Frame Shift Ins (INS) | VAF 42/168 reads (25%) | called by mutect2, pindel, varscan2
- SLC8A3 | c.1603del p.E535Nfs*35 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- TSC2 | c.4523_4524del p.P1508Lfs*15 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- VPS50 | c.2331del p.K778Nfs*7 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | called by mutect2, pindel, varscan2
- XRCC1 | c.1459del p.D487Tfs*6 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- ZNF718 | c.1323_1334del p.K442_H445del | In Frame Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel
- AHNAK | c.14301T>A p.P4767= | Silent (SNP) | VAF 75/360 reads (21%) | catalogued as rs1305874855, COSV57229489; called by muse, mutect2, varscan2
- ATP1A4 | c.2628T>C p.F876= | Silent (SNP) | VAF 42/173 reads (24%) | catalogued as COSV63628445; called by muse, mutect2, varscan2
- ATP6V1E1 | c.570A>C p.I190= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV53660185; called by muse, mutect2, varscan2
- C7 | c.2436G>A p.E812= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV57476003, COSV57480560; called by muse, mutect2, varscan2
- CCN3 | c.738G>A p.V246= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as rs777234634, COSV52385285; called by muse, varscan2
- CSRNP2 | c.57C>T p.G19= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as COSV57335354; called by muse, mutect2, varscan2
- CUL1 | c.1593A>G p.L531= | Silent (SNP) | VAF 30/209 reads (14%) | catalogued as rs764878022, COSV57392339; called by muse, mutect2, varscan2
- CYP46A1 | c.363C>T p.F121= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs780187016, COSV55894567; called by muse, mutect2, varscan2
- DPP6 | c.591T>C p.D197= (on ENST00000377770 / NM_001364500.2; = p.D135= on NM_001936.5) | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV59607126, COSV59643496; called by muse, mutect2, varscan2
- EBF2 | c.999C>T p.F333= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as COSV68780260; called by muse, mutect2, varscan2
- ERCC3 | c.1821A>T p.I607= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as COSV53425477, COSV53429832; called by muse, mutect2, varscan2
- EVPL | c.15G>T p.L5= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV56915529; called by muse, mutect2, varscan2
- FRMD5 | c.276C>T p.F92= | Silent (SNP) | VAF 101/277 reads (36%) | catalogued as COSV68725308; called by muse, mutect2, varscan2
- GFI1B | c.336C>A p.A112= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as COSV59746992; called by muse, mutect2, varscan2
- GIMAP8 | c.591A>T p.G197= | Silent (SNP) | VAF 63/199 reads (32%) | catalogued as COSV56233736; called by muse, mutect2, varscan2
- HFM1 | c.414T>A p.P138= | Silent (SNP) | VAF 63/215 reads (29%) | catalogued as COSV54036826; called by muse, mutect2, varscan2
- HSF2 | c.21G>T p.V7= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV63774567; called by muse, mutect2, varscan2
- IFNA13 | c.33C>A p.A11= | Silent (SNP) | VAF 44/149 reads (30%) | catalogued as COSV71924589; called by muse, mutect2, varscan2
- LRIG2 | c.2184C>T p.N728= | Silent (SNP) | VAF 72/194 reads (37%) | catalogued as COSV63164176; called by muse, mutect2, varscan2
- LRP1B | c.4962A>G p.L1654= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as rs756757502, COSV67272335; called by muse, mutect2, varscan2
- MAP3K19 | c.1980T>A p.P660= | Silent (SNP) | VAF 105/404 reads (26%) | catalogued as COSV59642077; called by muse, mutect2, varscan2
- OR1S2 | c.807A>G p.V269= | Silent (SNP) | VAF 18/264 reads (7%) | catalogued as COSV56920683; called by muse, mutect2
- OR4D10 | c.756G>A p.V252= | Silent (SNP) | VAF 52/272 reads (19%) | catalogued as COSV73260202; called by muse, mutect2, varscan2
- OR4S2 | c.201G>T p.V67= | Silent (SNP) | VAF 78/469 reads (17%) | catalogued as COSV56748323; called by muse, varscan2
- OR5B12 | c.474T>A p.T158= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV56904588, COSV56906654; called by muse, mutect2, varscan2
- OR5R1 | c.303G>T p.L101= | Silent (SNP) | VAF 80/145 reads (55%) | catalogued as COSV56573614; called by muse, mutect2
- OR9I1 | c.324A>T p.A108= | Silent (SNP) | VAF 62/116 reads (53%) | catalogued as COSV56927461; called by muse, mutect2, varscan2
- PCDH15 | c.1605C>T p.D535= | Silent (SNP) | VAF 59/153 reads (39%) | catalogued as rs370348265, COSV57271337; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHIP | c.2196A>T p.V732= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as COSV51510497; called by muse, mutect2, varscan2
- PPRC1 | c.4452G>T p.S1484= | Silent (SNP) | VAF 73/158 reads (46%) | catalogued as COSV53384631, COSV53388449; called by muse, mutect2, varscan2
- PRRC2C | c.3957G>C p.L1319= (on ENST00000367742; = p.L1317= on NM_015172.4) | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV58912724; called by muse, mutect2, varscan2
- PTK2 | c.1149C>A p.G383= | Silent (SNP) | VAF 156/704 reads (22%) | catalogued as COSV61792197; called by muse, mutect2, varscan2
- RAD54B | c.1134A>G p.L378= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as rs759006816, COSV60254717; called by muse, mutect2, varscan2
- RGS12 | c.3312G>A p.K1104= | Silent (SNP) | VAF 87/225 reads (39%) | catalogued as COSV58755501, COSV58756853; called by muse, mutect2, varscan2
- RGS7 | c.241T>C p.L81= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as COSV58553917; called by muse, mutect2, varscan2
- SCN1A | c.5352C>A p.V1784= (on ENST00000303395 / NM_001202435.3; = p.V1773= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/282 reads (29%) | catalogued as COSV57686503; called by muse, mutect2, varscan2
- SUSD3 | c.723G>T p.L241= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV64937521; called by muse, mutect2, varscan2
- SYNE1 | c.19998G>C p.L6666= (on ENST00000367255 / NM_182961.4; = p.L6595= on NM_033071.3) | Silent (SNP) | VAF 50/197 reads (25%) | catalogued as COSV55095669; called by muse, mutect2, varscan2
- TBC1D14 | c.786A>G p.L262= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV68987190; called by muse, mutect2, varscan2
- TBCC | c.831C>T p.S277= | Silent (SNP) | VAF 64/156 reads (41%) | catalogued as COSV55131151; called by muse, mutect2, varscan2
- THBS2 | c.138C>A p.R46= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs779026599, COSV64682095; called by muse, mutect2, varscan2
- THY1 | c.165C>A p.T55= | Silent (SNP) | VAF 33/264 reads (13%) | catalogued as COSV52455253; called by muse, mutect2, varscan2
- TNK2 | c.1986G>T p.G662= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs1458215557, COSV57375612; called by muse, mutect2
- TNN | c.837G>T p.L279= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV53435001; called by muse, mutect2, varscan2
- TRIM61 | c.465G>A p.V155= | Silent (SNP) | VAF 73/340 reads (21%) | catalogued as rs1408042618; called by muse, varscan2
- TTC26 | c.198T>C p.C66= | Silent (SNP) | VAF 47/225 reads (21%) | catalogued as COSV58274278; called by muse, mutect2, varscan2
- UNCX | c.339C>A p.T113= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as COSV100310287, COSV60332931, COSV60333656; called by muse, mutect2, varscan2
- USP30 | c.1302C>T p.Y434= | Silent (SNP) | VAF 96/244 reads (39%) | catalogued as rs773455265, COSV57451458; called by muse, mutect2, varscan2
- ZNF536 | c.1134C>T p.C378= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as rs755287534, COSV62820506; called by muse, mutect2, varscan2
- ZNF619 | c.1182C>T p.S394= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as COSV59031244; called by muse, mutect2, varscan2
- ZNF80 | c.717C>T p.H239= | Silent (SNP) | VAF 153/324 reads (47%) | catalogued as COSV57362483; called by muse, mutect2, varscan2
- RCC1 | c.73+591G>T | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100868158; called by muse, mutect2, varscan2
- SLC8A3 | c.1785-2956G>T | Intron (SNP) | VAF 17/115 reads (15%) | catalogued as COSV99385699, COSV99385745; called by muse, mutect2, varscan2
- TMEM234 | c.387+30C>G | Intron (SNP) | VAF 26/78 reads (33%) | catalogued as COSV100557237; called by muse, mutect2, varscan2
